Somatic mutation profile of tumor specimen TCGA-AG-A025-01A (aliquot TCGA-AG-A025-01A-01W-A00E-09) from TCGA case TCGA-AG-A025, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.8 years (22,952 days).
Specimen TCGA-AG-A025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69840457-26d8-473b-b5af-922a801ba64a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A025-10B (Blood Derived Normal), aliquot TCGA-AG-A025-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3509c71-1565-42b7-9fbc-29db4852a012

The open-access MAF lists 82 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 85/284 reads (30%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4133del p.Q1378Rfs*37 | Frame Shift Del (DEL) | VAF 95/268 reads (35%) | catalogued as COSV57338279; called by mutect2, pindel, varscan2
- ARHGAP36 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1200019083, COSV52267262; called by muse, mutect2, varscan2
- BABAM2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.096); catalogued as rs1181189911, COSV59623920; called by muse, mutect2, varscan2
- BRPF3 | c.762G>T p.W254C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60206478, COSV60207618; called by muse, mutect2, varscan2
- BUB1 | c.93A>G p.I31M | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.049); catalogued as rs752373314, COSV57063799; called by muse, mutect2, varscan2
- CCKBR | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV58101781; called by muse, mutect2, varscan2
- CDKN1B | c.222C>G p.Y74* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as COSV57430528; called by muse, mutect2, varscan2
- CHD9 | c.2699A>G p.Y900C | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as rs370605180; called by muse, mutect2, varscan2
- CSMD2 | c.9469C>T p.R3157C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs143597727; called by muse, mutect2, varscan2
- CTSV | c.167T>G p.M56R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV52344895; called by muse, mutect2, varscan2
- DNAJC7 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV57269018; called by muse, mutect2
- DSEL | c.379T>G p.W127G | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59491840; called by muse, mutect2, varscan2
- EFNB3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs759236058, COSV56833542; called by muse, mutect2, varscan2
- FBXO3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV55766334; called by muse, mutect2, varscan2
- FILIP1 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 261/675 reads (39%) | catalogued as rs1470989448, COSV52730636; called by muse, mutect2, varscan2
- GPR75 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV100765846, COSV61827793; called by muse, mutect2, varscan2
- GRM1 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs1478519321, COSV51154449; called by muse, mutect2, varscan2
- HECTD4 | c.8456G>A p.R2819Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs535700898, COSV66392547; called by muse, mutect2, varscan2
- KDM4A | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs200705318, COSV64959639; called by muse, mutect2, varscan2
- LMAN2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV57424683; called by muse, mutect2, varscan2
- LRRTM2 | c.989A>T p.Q330L | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV51220957; called by muse, mutect2, varscan2
- MYO18B | c.5683C>T p.R1895C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs368617132; called by muse, mutect2, varscan2
- NSUN4 | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV61063178; called by muse, mutect2, varscan2
- OR5K2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs755600607, COSV71143213; called by muse, mutect2, varscan2
- OR6C3 | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 203/625 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as rs767047709, COSV65571020; called by muse, mutect2, varscan2
- OR8I2 | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 89/234 reads (38%) | catalogued as COSV56168211; called by muse, mutect2, varscan2
- OTOGL | c.2890T>A p.Y964N (on ENST00000547103; = p.Y955N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72006672; called by muse, mutect2
- PCDHA6 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV65343372; called by muse, mutect2, varscan2
- PCDHB12 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV53396961; called by muse, mutect2, varscan2
- PCDHB3 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV50576521; called by muse, mutect2, varscan2
- PI4KA | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs202070171, COSV55411988; called by mutect2, varscan2
- PIK3R1 | c.1508G>A p.R503Q (on ENST00000521381 / NM_181523.3; = p.R233Q on NM_181504.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs765178503, COSV57130875; called by muse, mutect2, varscan2
- POMT2 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV55071364; called by muse, mutect2
- PRKAA2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 211/625 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.169); catalogued as rs1031612391, COSV64803952; called by muse, mutect2, varscan2
- PRM2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV54113256; called by muse, mutect2, varscan2
- PTDSS1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375073869; called by muse, mutect2, varscan2
- RANBP3L | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs146572714; called by muse, mutect2, varscan2
- RPS4X | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as COSV60181674; called by muse, mutect2, varscan2
- RYR2 | c.4847G>T p.G1616V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63687421; called by muse, mutect2, varscan2
- SESTD1 | c.1486A>C p.M496L | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58931394; called by muse, mutect2, varscan2
- SLC14A1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.354); catalogued as rs367901541; called by muse, mutect2, varscan2
- SLITRK4 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs374198793, COSV62024856; called by muse, varscan2
- ST7 | c.989G>A p.S330N (on ENST00000265437 / NM_021908.3; = p.S307N on NM_018412.4) | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as rs750116179, COSV55385431; called by muse, mutect2, varscan2
- SYNE1 | c.508C>T p.R170W (on ENST00000367255 / NM_182961.4; = p.R177W on NM_033071.3) | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777175001, COSV54897233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.96871_96872del p.H32292* (on ENST00000591111; = p.H24868* on NM_003319.4) | Frame Shift Del (DEL) | VAF 48/153 reads (31%) | catalogued as COSV60087269; called by mutect2, pindel, varscan2
- TTN | c.30461T>A p.V10154D (on ENST00000591111; = p.V9227D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | PolyPhen benign (0.134); catalogued as COSV60087286; called by muse, mutect2, varscan2
- VEPH1 | c.1260C>A p.S420R | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV62879164; called by muse, varscan2
- ZNF561 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 102/145 reads (70%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as COSV57177337; called by muse, mutect2, varscan2
- ZNF593 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54631332; called by muse, mutect2, varscan2
- ATP8B2 | c.1803C>A p.D601E (on ENST00000672630; = p.D568E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CDYL | c.42C>G p.S14R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DNAJC2 | c.131_132del p.R44Kfs*12 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, pindel, varscan2
- KCNRG | c.57_73del p.F20Vfs*31 | Frame Shift Del (DEL) | VAF 60/384 reads (16%) | called by mutect2, pindel
- OTOGL | c.2892T>G p.Y964* (on ENST00000547103; = p.Y955* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/522 reads (7%) | called by muse, mutect2
- SH3PXD2A | c.2159C>T p.P720L (on ENST00000369774 / NM_001365079.1; = p.P692L on NM_014631.2) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- SOX9 | c.811dup p.R271Pfs*25 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- ANK2 | c.3969C>T p.C1323= | Silent (SNP) | VAF 116/364 reads (32%) | catalogued as rs756674393, COSV52162898; called by muse, mutect2, varscan2
- CACNA1B | c.5769C>T p.G1923= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs201682730, COSV53121374; called by muse, mutect2, varscan2
- CACNG6 | c.669C>T p.C223= (on ENST00000252729 / NM_145814.1; = p.C152= on NM_031897.2) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs199614002, COSV53166802; called by muse, mutect2, varscan2
- CYP2A13 | c.810C>G p.S270= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV57838000, COSV57839990; called by muse, mutect2, varscan2
- ENPEP | c.897A>G p.R299= | Silent (SNP) | VAF 43/258 reads (17%) | catalogued as COSV54448896; called by muse, mutect2, varscan2
- FZD2 | c.1344C>T p.D448= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs765137220, COSV59528710; called by muse, mutect2, varscan2
- GAD2 | c.729C>T p.G243= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs149136572, COSV52156924; called by muse, mutect2, varscan2
- HLCS | c.258T>C p.A86= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV60793886; called by muse, mutect2, varscan2
- JADE1 | c.1956G>A p.V652= | Silent (SNP) | VAF 95/271 reads (35%) | catalogued as COSV56906144; called by muse, mutect2, varscan2
- MIOS | c.1176G>A p.T392= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV60768593; called by muse, mutect2, varscan2
- NCAPG2 | c.558T>A p.L186= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV51988021; called by muse, mutect2, varscan2
- NGFR | c.615G>A p.S205= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs377669981; called by muse, mutect2
- NPAP1 | c.738C>T p.A246= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs753676478, COSV100274843, COSV61507402; called by muse, mutect2, varscan2
- PAPPA | c.1305C>T p.H435= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs371022168; called by muse, mutect2, varscan2
- PEX6 | c.2397T>C p.I799= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs773184108, COSV55103326; called by muse, mutect2, varscan2
- PTPN5 | c.825C>T p.R275= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs907135096, COSV62126078; called by muse, mutect2, varscan2
- PXDN | c.1485C>T p.H495= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs765374054, COSV53234843; called by muse, mutect2, varscan2
- RSAD2 | c.873T>C p.P291= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs1332941008, COSV65908373; called by muse, mutect2, varscan2
- SCGN | c.738C>T p.R246= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as rs1475330156, COSV58545678; called by muse, mutect2, varscan2
- TMCC3 | c.855C>A p.G285= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1566315305, COSV54154618, COSV99705207; called by muse, mutect2, varscan2
- TMOD3 | c.186G>A p.G62= | Silent (SNP) | VAF 133/336 reads (40%) | catalogued as COSV57943937; called by muse, varscan2
- CPLANE1 | chr5:37167060 C>A | 3'Flank (SNP) | VAF 26/87 reads (30%) | catalogued as COSV57061039; called by muse, mutect2, varscan2
- CTPS2 | c.1393+264T>C | Intron (SNP) | VAF 66/200 reads (33%) | called by muse, mutect2, varscan2
- PLCXD2 | c.*45T>A | 3'UTR (SNP) | VAF 17/89 reads (19%) | catalogued as COSV67311388; called by muse, mutect2, varscan2
